Gene-level copy-number profile of tumor specimen CUPP-B528-TTM1-A from CCG case CUPP-B528, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, metastatic, NOS; Tissue or organ of origin: Unknown primary site; Age at diagnosis: 56.8 years (20,751 days).
Specimen CUPP-B528-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6a083b7a-2aaf-410c-bed5-a42387817de3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CUPP-B528-NT1-A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/5dd26899-49ad-4d09-9c4f-858b18fea675

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 122; copy number 1: 30,722; copy number 2: 27,682; copy number 3: 292; copy number 4: 48; copy number 5: 19; copy number 6: 11; copy number 11: 1; copy number 20: 1.

Homozygous deletions (total copy number 0; autosomes only): 119 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,488,300–11,488,473, 1 gene (within-gene range 0–1): AC026185.1.
- chr3:25,441,164–25,441,502, 1 gene (within-gene range 0–1): H3P10.
- chr3:39,970,125–39,970,266, 1 gene (within-gene range 0–1): RNU4-56P.
- chr3:85,799,987–85,828,050, 1 gene (within-gene range 0–1): CADM2-AS2.
- chr4:1,027,678–1,028,972, 1 gene: AC019103.1.
- chr5:15,384,220–15,384,853, 1 gene: MARK2P5.
- chr5:67,001,383–67,003,953, 1 gene (within-gene range 0–1): MAST4-AS1.
- chr5:67,690,033–67,902,600, 3 genes (within-gene range 0–1): AC112206.4, AC112206.3, AC106798.1.
- chr5:103,246,048–103,278,660, 2 genes: AC011362.1, MACIR.
- chr7:138,701,607–138,703,062, 1 gene: UQCRFS1P2.
- chr8:12,290,071–12,296,180, 1 gene: DEFB131D.
- chr8:12,333,644–12,333,693, 1 gene: RNA5SP254.
- chr8:19,237,737–19,249,240, 2 genes (within-gene range 0–1): AC068880.1, AC068880.3.
- chr8:42,541,155–42,555,195, 1 gene (within-gene range 0–1): SMIM19.
- chr8:42,896,197–42,896,275, 1 gene (within-gene range 0–2): MIR4469.
- chr8:143,597,831–143,603,224, 1 gene (within-gene range 0–1): TIGD5.
- chr9:22,203,990–22,214,672, 1 gene: AL157937.1.
- chr9:136,796,338–136,829,466, 4 genes (within-gene range 0–2): CCDC183, AL355987.4, AL355987.2, CCDC183-AS1.
- chr9:136,812,788–136,831,023, 2 genes (within-gene range 0–1): NCLP1, MIR4292.
- chr9:136,935,840–136,937,988, 2 genes (within-gene range 0–1): AL807752.1, AL807752.5.
- chr9:136,949,551–136,955,497, 1 gene (within-gene range 0–1): LCN12.
- chr9:136,975,092–136,985,435, 2 genes (within-gene range 0–1): PTGDS, AL807752.7.
- chr9:137,007,234–137,028,922, 1 gene (within-gene range 0–1): ABCA2.
- chr11:34,709,600–34,743,199, 2 genes: AC087783.1, AL359999.1.
- chr12:75,688,794–75,698,816, 3 genes (within-gene range 0–1): RPL10P13, SNORA70, AC078820.1.
- chr16:968,375–969,012, 1 gene (within-gene range 0–1): AC009041.3.
- chr16:1,064,093–1,080,142, 3 genes: SSTR5-AS1, AC009041.2, SSTR5.
- chr17:15,699,577–15,744,778, 3 genes (within-gene range 0–2): ZNF286A, AC005324.3, UBE2SP1.
- chr20:8,248,704–8,256,918, 1 gene (within-gene range 0–1): PLCB1-IT1.
- chr21:7,744,962–8,454,792, 26 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.
- chr21:8,701,461–13,120,807, 45 genes: CR381572.1, LINC01666, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2, CR381653.1, SNX18P12, CR381653.2, NCOR1P4, AC124864.1, AC124864.2, U1, LINC01667, AC018692.2, RN7SL52P, SNORA70, AC018692.1, CR382285.1, CR382285.2, CR382287.1, CDRT15P8, AP003900.1, EIF3FP1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr21:16,417,139–16,419,080, 1 gene (within-gene range 0–1): AP001172.2.
- chr21:16,525,919–16,527,019, 1 gene (within-gene range 0–1): AP000962.2.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 372 genes in 68 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,709,235–116,723,581, 2 genes, copy number 3 (within-gene range 2–3): TUSC7, AC108713.1.
- chr3:162,486,541–162,601,792, 2 genes, copy number 3: TOMM22P6, AC128716.1.
- chr3:164,670,878–164,831,480, 2 genes, copy number 3: LINC01323, LINC01324.
- chr3:166,835,021–167,066,320, 3 genes, copy number 3–4: AC069439.2, AC069439.1, PPIAP74.
- chr3:168,249,522–168,830,599, 2 genes, copy number 3 (within-gene range 2–4): EGFEM1P, AC124893.1.
- chr3:169,709,295–169,720,293, 2 genes, copy number 3: SDHDP3, RNU6-637P.
- chr3:172,889,357–174,378,005, 8 genes, copy number 3–5: SPATA16, AC068759.1, NLGN1, AC092967.1, NLGN1-AS1, RN7SKP234, ANAPC15P2, AC069218.1.
- chr3:179,452,395–179,465,328, 2 genes, copy number 3: AC007620.1, MTHFD2P7.
- chr3:187,383,101–187,449,450, 3 genes, copy number 3: AC068299.2, AC068299.1, LINC02041.
- chr3:190,852,737–191,330,536, 4 genes, copy number 3 (within-gene range 2–3): GMNC, OSTN, OSTN-AS1, UTS2B.
- chr3:193,144,464–193,176,864, 2 genes, copy number 3: AC092966.1, VEZF1P1.
- chr3:194,394,821–194,521,156, 5 genes, copy number 3: GP5, ATP13A3, AC108676.2, LINC00884, AC108676.1.
- chr3:194,587,673–195,152,790, 14 genes, copy number 3 (within-gene range 2–3): TMEM44, AC046143.1, AC046143.2, LSG1, FAM43A, AC106706.1, AC106706.2, LINC01968, AC090505.1, LINC01972, AC090505.2, XXYLT1-AS1, MIR3137, XXYLT1-AS2.
- chr3:195,260,632–195,443,044, 2 genes, copy number 3 (within-gene range 2–3): AC090018.2, ACAP2.
- chr3:195,349,664–195,419,546, 2 genes, copy number 3: AC090018.1, Y_RNA.
- chr3:195,553,792–195,990,318, 23 genes, copy number 3–4: RN7SL73P, AC069213.3, AC069213.2, APOD, MUC20P1, AC233280.2, AC233280.1, MUC20-OT1, SDHAP2, MIR570, SMBD1P, MUC20, MUC4, LINC01983, KIF3AP1, TNK2, MIR6829, AC124944.3, TNK2-AS1, AC124944.2, RNU2-11P, AC124944.1, SDHAP1.
- chr3:196,027,183–196,515,346, 26 genes, copy number 3: TFRC, AC024937.1, RNU7-18P, LINC00885, ZDHHC19, Y_RNA, SLC51A, PCYT1A, AC069257.3, AC069257.1, TCTEX1D2, AC069257.2, TM4SF19-TCTEX1D2, TM4SF19-AS1, TM4SF19, RNU6-910P, UBXN7, RNU6-1279P, RN7SL434P, RN7SL738P, AC083822.1, UBXN7-AS1, AC117490.1, RNF168, AC117490.2, SMCO1.
- chr3:198,053,522–198,123,232, 5 genes, copy number 3: ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1.
- chr5:92,151–667,168, 24 genes, copy number 3–20 (within-gene range 2–20): PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72.
- chr5:6,019,029–6,137,171, 3 genes, copy number 3: AC010266.2, AC010266.1, AC026797.1.
- chr5:17,444,010–17,498,827, 4 genes, copy number 4: LINC02218, H3Y2, AC106774.1, TAF11L2.
- chr5:17,597,232–17,605,377, 4 genes, copy number 3: TAF11L10, AC233724.3, AC233724.6, TAF11L11.
- chr5:17,632,088–17,670,571, 9 genes, copy number 4: TAF11L13, TAF11L14, AC233724.4, AC233724.1, AC233724.5, AC233724.2, H3Y1, AC233724.8, H3P22.
- chr5:35,429,064–36,151,887, 13 genes, copy number 3 (within-gene range 2–3): U3, SPEF2, RNU7-130P, AC137810.1, IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2.
- chr5:37,288,137–38,465,480, 19 genes, copy number 3–5 (within-gene range 2–5): NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P, RNU6-484P, GDNF-AS1, GDNF, LINC02117, AC008869.1, LINC02110, AC034226.1, LINC02119, AC010338.1, EGFLAM, EGFLAM-AS4, EGFLAM-AS3, EGFLAM-AS2.
- chr7:93,099,513–93,911,265, 13 genes, copy number 3 (within-gene range 2–3): SAMD9, SAMD9L, HEPACAM2, VPS50, CALCR, MIR653, MIR489, GNGT1, AC002075.2, MIR4652, AC002075.1, NDUFAF4P2, TFPI2.
- chr7:95,772,506–97,437,896, 22 genes, copy number 3–5: DYNC1I1, AC002540.1, SLC25A13, MIR591, AC096775.1, AC084368.1, RNU6-532P, RNU6-364P, RNU7-188P, SEM1, MARK2P10, RN7SL252P, DLX6-AS1, AC004774.1, AC004774.3, DLX6, AC004774.2, DLX5, SDHAF3, HMGB3P21, AC073900.1, AP1S2P1.
- chr7:98,454,119–98,629,869, 3 genes, copy number 3–5: PPIAP82, AC074121.1, NPTX2.
- chr7:100,949,534–101,097,967, 7 genes, copy number 3–4: MUC3A, AC254629.1, MUC12, MUC12-AS1, MUC17, RN7SKP54, TRIM56.
- chr7:101,154,456–102,283,958, 24 genes, copy number 3 (within-gene range 2–3): AP1S1, MIR4653, VGF, NAT16, MOGAT3, DGAT2L7P, RPSAP46, PLOD3, ZNHIT1, CLDN15, FIS1, RNU6-1104P, AC006329.1, AZGP1P2, LNCPRESS1, EMSLR, IFT22, COL26A1, AC004965.1, LINC01007, MYL10, CUX1, AC005096.1, AC005072.1.
- chr7:109,322,320–109,999,624, 6 genes, copy number 3: AC002386.1, AC073071.1, AC073387.1, AC073387.2, EIF3IP1, RPL3P8.
- chr8:12,341,426–12,388,296, 3 genes, copy number 3–6 (within-gene range 2–6): DEFB108E, ZNF705CP, FAM66A.
- chr11:55,979,398–55,994,625, 2 genes, copy number 3: OR7E5P, OR5F1.
- chr11:56,159,394–56,347,031, 15 genes, copy number 3: OR8K5, OR5J7P, OR5J2, OR8V1P, AC022882.1, OR8J2, OR5T2, OR5T3, OR5T1, OR8H1, OR8I1P, OR8K3, FAM8A2P, OR8K2P, OR8K1.
- chr11:56,412,696–56,543,281, 14 genes, copy number 3: OR5AL1, OR5R1, OR5M4P, AP002512.3, OR5M9, OR5M3, OR5M2P, OR5M8, AP002512.1, OR5M7P, AP002512.2, OR5M6P, OR5M5P, OR5M11.
- chr11:60,040,409–60,098,467, 4 genes, copy number 3–5: OOSP2, MS4A3, AP000790.2, MS4A2.
- chr11:70,078,302–71,452,868, 26 genes, copy number 3–6 (within-gene range 1–6): ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1, ACTE1P, DHCR7.
- chr16:1,528,688–1,555,580, 2 genes, copy number 3 (within-gene range 1–3): TMEM204, AL031719.1.
- chr19:22,595,479–22,623,971, 8 genes, copy number 3 (within-gene range 3–5): AC011467.5, GOLGA2P9, RN7SL860P, AC011467.3, AC011467.4, RAD54L2P1, LINC01785, AC011467.2.
- chr21:8,603,547–8,680,934, 2 genes, copy number 3–6: RPSAP68, CR381572.2.

Autosomal genes at a single copy (total copy number 1): 27,874. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
